ALCHEMIST case ALCH-ABC2 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/be3ab65e-4864-4a11-af72-cb9a88b6db8c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 63.7 years (23,249 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ABC2-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ABC2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide ALCH-ABC2-TTP1-A-1-0-S2: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 15; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 75; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 10.
  Slide ALCH-ABC2-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 15; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 8.
